Gene-level copy-number profile of tumor specimen ALCH-B2CT-TTP1-A from ALCHEMIST case ALCH-B2CT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 67.6 years (24,686 days).
Specimen ALCH-B2CT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8685fbfc-0fe6-4f7a-a04d-2c3989e471f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2CT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/c2a3e754-ade8-438f-ad1f-cba19190835e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 23,893; copy number 2: 30,825; copy number 3: 3,501; copy number 4: 634; copy number 5: 10; copy number 6: 4; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,025,247–70,132,973, 5 genes: SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3.
- chr8:37,600,537–37,625,873, 1 gene: AC137579.2.
- chr13:40,789,412–40,812,460, 1 gene (within-gene range 0–1): SLC25A15.
- chr15:22,178,107–22,185,402, 2 genes: IGHV1OR15-3, IGHV4OR15-8.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.
- chr15:74,782,057–74,803,198, 2 genes: CSK, MIR4513.
- chr15:74,843,730–74,873,365, 1 gene: SCAMP2.
- chr17:28,246,454–28,265,551, 4 genes (within-gene range 0–2): AC061975.6, PPY2P, AC061975.2, AC061975.4.
- chr19:1,103,926–1,106,791, 1 gene: GPX4.
- chr19:5,558,167–5,578,349, 1 gene (within-gene range 0–2): TINCR.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:30,516,079–30,600,647, 7 genes, copy number 5: AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8.
- chr21:44,133,610–44,210,114, 4 genes, copy number 6 (within-gene range 1–6): GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:18,846,811–18,861,049, 2 genes, copy number 14: AC008132.1, BCRP7.
- chr22:18,906,028–18,947,732, 3 genes, copy number 5 (within-gene range 1–5): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 21,068. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
